Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81P-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: left adrenal

There is a sharply separated redish, inhomogenous tumor with a diameter of 2.2 cm. Histologically, the tumor is composed zellballen and aeas with trabecular architecture. Cells are medium sized, modestly pleomorph, with partly enlarged nuclei and small nucleoli with chromatin. The cytoplasm is amphophilic and granular. The tumor is surrounded by a thin fibrous capsule which is destroyed by the tumor on two locations. There, invasion into the adjacent adipose tissue was noted. The tumor is lacerated with a hematoma, which is the reason why a complete resection could not be proven histologically. In the middle of the tumor, a fibrous area with bleeding residues is present. No evidence for necrosis, vessel invasion, no increased number in mitosis or atypical mitosis.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3

Pheochromocytoma NOS 8700/0
Site ① Adrenal gland NOS C74.9

JW 10/17/13

Source: NCI Genomic Data Commons file cecdeddc-3223-4da3-a044-8ba0679b0fb2 (TCGA-WB-A81P.9B4D9362-BDD4-488D-98B3-19C9EE5DF17E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).